Somatic mutation profile of tumor specimen MP2PRT-PAUIBC-TMP1-A (aliquot MP2PRT-PAUIBC-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUIBC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,021 days).
Specimen MP2PRT-PAUIBC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d2e3d8f-5bbd-4f51-b072-bf86924590a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUIBC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUIBC-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c40488e-3511-48a2-a933-15c8ae66fee0

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBA2 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 141/438 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs372888964; called by muse, mutect2, varscan2
- ATP7A | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs201999500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL3 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 16/599 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1556560595, COSV57754791; called by muse, mutect2
- RRAD | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 126/406 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs528970997; called by muse, mutect2, varscan2
- AFG3L2 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- FAM187A | c.408C>G p.Y136* | Nonsense Mutation (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2
- PPEF1 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLITRK2 | c.2177A>T p.K726I | Missense Mutation (SNP) | VAF 156/489 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CPVL | c.693C>T p.N231= | Silent (SNP) | VAF 73/253 reads (29%) | catalogued as rs147609298, COSV99606600; called by muse, mutect2, varscan2
- IGHV4-61 | chr14:106639118 ins GGA | 3'Flank (INS) | VAF 4/18 reads (22%) | called by pindel, varscan2
